Surgical pathology report (de-identified scan), TCGA case TCGA-Q1-A6DT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q1-A6DT-01A (Primary Tumor).

RUN DATE:
RUN TIME:
BY:

LABORATORY

PAGE:1

Specimen Inquiry

SPEC #:
STATUS:

Obtained:
Received:

Subm Dr:

CLINICAL HISTORY:
CERVICAL CANCER

SPECIMEN/PROCEDURE:
1. CERVICAL BIOPSY

ICD-O-3
Carcinoma squamous cell
large cell (non-keratinizing) 8072/3
Site: Cervix NOS 253.9
JW 6/13/13

IMPRESSION:

CERVICAL BIOPSY:

Squamous cell carcinoma, large cell nonkeratinizing with stromal invasion.

Dictated by:
Entered:

GROSS DESCRIPTION:

Received without fixative labeled "cervical biopsy" and with the patient's name, is one irregular pink-tan to pale tan glistening portion of tissue, 1.8 x 1.4 x 0.8 cm. The specimen is serially sectioned and entirely submitted in one cassette.

Dictated by:
Entered:

COPIES TO:

CPT Codes:

CERVICAL BIOPSY/88305

ICD9 Codes:

180.9

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by:

Physicians

** END OF REPORT **

Source: NCI Genomic Data Commons file 61096c33-8b51-4cf9-835a-8dded9255691 (TCGA-Q1-A6DT.1EB62CB3-7D11-4C4D-B893-5E9B2146C4D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).